Somatic mutation profile of tumor specimen TCGA-DD-A39Z-01A (aliquot TCGA-DD-A39Z-01A-11D-A20W-10) from TCGA case TCGA-DD-A39Z, project TCGA-LIHC (Liver Hepatocellular Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Hepatocellular carcinoma, NOS; Tissue or organ of origin: Liver; AJCC pathologic stage: Stage II; Tumor grade: G2; Age at diagnosis: 43.6 years (15,930 days).
Specimen TCGA-DD-A39Z-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3868d8cc-c0dd-4db2-8d0d-830760321e79.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DD-A39Z-11A (Solid Tissue Normal), aliquot TCGA-DD-A39Z-11A-21D-A20W-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/511d6243-f6f4-41e0-91ed-04dbddb5c1ed

The open-access MAF lists 77 somatic variants for this specimen: 60 protein-altering or splice-affecting, 16 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 48, Silent 16, Nonsense Mutation 6, Splice Site 3, Frame Shift Del 3, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADGRB1 | c.3035C>T p.T1012M | Missense Mutation (SNP) | VAF 16/48 reads (33%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.752); catalogued as rs761237409, COSV60103588; called by muse, mutect2, varscan2
- ALMS1 | c.7751A>G p.K2584R | Missense Mutation (SNP) | VAF 21/48 reads (44%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.86); catalogued as COSV52522475; called by muse, mutect2, varscan2
- AP1G1 | c.853G>T p.G285* | Nonsense Mutation (SNP) | VAF 60/78 reads (77%) | catalogued as COSV55495539; called by muse, mutect2, varscan2
- ATG2B | c.1381G>T p.E461* | Nonsense Mutation (SNP) | VAF 77/204 reads (38%) | catalogued as COSV63425755; called by muse, mutect2, varscan2
- AXIN1 | c.964del p.E322Sfs*92 | Frame Shift Del (DEL) | VAF 23/40 reads (58%) | catalogued as COSV51986728, COSV51990434, COSV99249701; called by mutect2, pindel, varscan2
- AZU1 | c.183C>G p.F61L | Missense Mutation (SNP) | VAF 12/48 reads (25%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV52140193, COSV52142696; called by muse, mutect2, varscan2
- BRD7 | c.888G>T p.K296N | Missense Mutation (SNP) | VAF 30/44 reads (68%) | SIFT tolerated (0.06); PolyPhen benign (0.122); catalogued as COSV101164509; called by muse, mutect2, varscan2
- BRD7 | c.888-1G>A p.X296_splice | Splice Site (SNP) | VAF 30/43 reads (70%) | catalogued as COSV101164512; called by muse, mutect2, varscan2
- CD1E | c.769G>A p.G257R | Missense Mutation (SNP) | VAF 63/226 reads (28%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.928); catalogued as COSV63773044, COSV63773330; called by muse, mutect2, varscan2
- CDKN3 | c.215T>C p.I72T | Missense Mutation (SNP) | VAF 24/39 reads (62%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.784); catalogued as rs1314092141, COSV53593937; called by muse, mutect2, varscan2
- COP1 | c.1792C>T p.H598Y | Missense Mutation (SNP) | VAF 42/181 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as COSV58176453; called by muse, mutect2, varscan2
- CPSF1 | c.3811G>T p.V1271L | Missense Mutation (SNP) | VAF 43/149 reads (29%) | SIFT deleterious (0.03); PolyPhen benign (0.38); catalogued as COSV58235655, COSV58235798; called by muse, mutect2, varscan2
- CTAGE15 | c.1186A>C p.M396L | Missense Mutation (SNP) | VAF 69/708 reads (10%) | SIFT tolerated (0.28); PolyPhen benign (0.087); catalogued as COSV69482234; called by muse, mutect2, varscan2
- DSCAM | c.4231+1G>C p.X1411_splice | Splice Site (SNP) | VAF 28/77 reads (36%) | catalogued as COSV68036642; called by muse, mutect2, varscan2
- DSCAM | c.4231G>T p.G1411* | Nonsense Mutation (SNP) | VAF 29/76 reads (38%) | catalogued as COSV68036650; called by muse, mutect2, varscan2
- E2F1 | c.815A>T p.Q272L | Missense Mutation (SNP) | VAF 44/104 reads (42%) | SIFT deleterious (0.01); PolyPhen benign (0.179); catalogued as COSV55778748; called by muse, mutect2, varscan2
- EDEM1 | c.1655G>C p.S552T | Missense Mutation (SNP) | VAF 30/70 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV56584255; called by muse, mutect2, varscan2
- EGFLAM | c.207+2T>C p.X69_splice | Splice Site (SNP) | VAF 24/51 reads (47%) | catalogued as COSV59318437; called by muse, mutect2, varscan2
- EMILIN2 | c.789G>T p.K263N | Missense Mutation (SNP) | VAF 19/38 reads (50%) | SIFT tolerated (0.07); PolyPhen benign (0.365); catalogued as COSV54427752; called by muse, mutect2, varscan2
- EPPK1 | c.3133G>A p.A1045T | Missense Mutation (SNP) | VAF 50/138 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.878); catalogued as COSV73262395; called by muse, mutect2, varscan2
- FBXL4 | c.455T>G p.I152S | Missense Mutation (SNP) | VAF 42/58 reads (72%) | SIFT deleterious (0); PolyPhen benign (0.134); catalogued as COSV57750147; called by muse, mutect2, varscan2
- FLOT1 | c.709G>T p.A237S | Missense Mutation (SNP) | VAF 20/77 reads (26%) | SIFT tolerated (0.06); PolyPhen benign (0.117); catalogued as COSV52544632; called by muse, mutect2, varscan2
- FMNL2 | c.757C>G p.L253V | Missense Mutation (SNP) | VAF 18/47 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV56504935; called by muse, mutect2, varscan2
- GPR84 | c.446T>C p.V149A | Missense Mutation (SNP) | VAF 22/44 reads (50%) | SIFT tolerated (0.22); PolyPhen benign (0.062); catalogued as COSV57210452; called by muse, mutect2, varscan2
- ICAM3 | c.149T>C p.F50S | Missense Mutation (SNP) | VAF 6/66 reads (9%) | SIFT tolerated (0.42); PolyPhen benign (0); catalogued as COSV50330216; called by muse, mutect2
- LRP2 | c.3040G>A p.E1014K | Missense Mutation (SNP) | VAF 48/139 reads (35%) | SIFT tolerated (0.71); PolyPhen benign (0.042); catalogued as rs781041064, COSV55575447; called by muse, mutect2, varscan2
- MARCHF4 | c.1058G>A p.G353D | Missense Mutation (SNP) | VAF 32/93 reads (34%) | SIFT deleterious (0.05); PolyPhen benign (0); catalogued as rs973671685, COSV56108781; called by muse, mutect2, varscan2
- MUC16 | c.4517C>T p.T1506I | Missense Mutation (SNP) | VAF 27/63 reads (43%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.958); catalogued as COSV67495401; called by muse, mutect2, varscan2
- NDUFAF7 | c.383G>A p.G128E | Missense Mutation (SNP) | VAF 17/34 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50018955; called by muse, mutect2, varscan2
- NLGN1 | c.1582T>G p.F528V | Missense Mutation (SNP) | VAF 85/183 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV64347370; called by muse, mutect2, varscan2
- NUP62 | c.962G>A p.G321E | Missense Mutation (SNP) | VAF 12/36 reads (33%) | SIFT tolerated (0.28); PolyPhen benign (0.158); catalogued as rs766750131, COSV61313778; called by muse, mutect2, varscan2
- PAK1IP1 | c.250A>G p.T84A | Missense Mutation (SNP) | VAF 16/68 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.371); catalogued as rs751776397, COSV65435973; called by mutect2, varscan2
- PEAK1 | c.307G>C p.G103R | Missense Mutation (SNP) | VAF 43/118 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.08); catalogued as COSV56943581; called by muse, mutect2, varscan2
- PEG3 | c.2866C>A p.P956T | Missense Mutation (SNP) | VAF 42/112 reads (38%) | SIFT tolerated (0.4); PolyPhen benign (0.052); catalogued as COSV55648307; called by muse, mutect2, varscan2
- PGGT1B | c.1121A>G p.H374R | Missense Mutation (SNP) | VAF 46/138 reads (33%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.005); catalogued as rs748433127, COSV56975287; called by muse, mutect2, varscan2
- PSG7 | c.1037C>A p.S346* | Nonsense Mutation (SNP) | VAF 39/82 reads (48%) | catalogued as COSV68446676; called by muse, mutect2, varscan2
- RGS4 | c.50A>G p.K17R | Missense Mutation (SNP) | VAF 19/67 reads (28%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); catalogued as COSV63358225; called by muse, mutect2, varscan2
- RHOH | c.530G>A p.R177Q | Missense Mutation (SNP) | VAF 10/97 reads (10%) | SIFT tolerated (0.45); PolyPhen benign (0); catalogued as rs1244021714, COSV67806482; called by muse, mutect2, varscan2
- RLF | c.4732A>G p.S1578G | Missense Mutation (SNP) | VAF 13/41 reads (32%) | SIFT tolerated (0.61); PolyPhen benign (0.065); catalogued as COSV65653265; called by muse, mutect2, varscan2
- RP1 | c.6226T>A p.F2076I | Missense Mutation (SNP) | VAF 23/65 reads (35%) | SIFT deleterious (0.02); PolyPhen benign (0.163); catalogued as COSV55127320; called by muse, mutect2, varscan2
- RP1L1 | c.7102G>A p.E2368K | Missense Mutation (SNP) | VAF 23/30 reads (77%) | SIFT tolerated (0.14); PolyPhen benign (0.006); catalogued as COSV66760573; called by muse, mutect2, varscan2
- RRM1 | c.1033A>T p.N345Y | Missense Mutation (SNP) | VAF 39/94 reads (41%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.908); catalogued as COSV56166326; called by muse, mutect2, varscan2
- SCRIB | c.1934G>A p.W645* | Nonsense Mutation (SNP) | VAF 11/47 reads (23%) | catalogued as COSV57593455; called by muse, mutect2, varscan2
- SDK1 | c.2798G>A p.G933E | Missense Mutation (SNP) | VAF 71/182 reads (39%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.996); catalogued as COSV67389170; called by muse, mutect2, varscan2
- SH2D7 | c.874C>T p.P292S | Missense Mutation (SNP) | VAF 39/61 reads (64%) | SIFT tolerated (0.09); PolyPhen benign (0.001); catalogued as COSV51950173; called by muse, mutect2, varscan2
- SNX13 | c.164C>T p.S55L | Missense Mutation (SNP) | VAF 36/179 reads (20%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.607); catalogued as COSV68068260; called by muse, mutect2, varscan2
- SYT4 | c.787G>T p.G263* | Nonsense Mutation (SNP) | VAF 53/122 reads (43%) | catalogued as COSV54899091, COSV54904328; called by muse, mutect2, varscan2
- TLR2 | c.1390G>A p.V464I | Missense Mutation (SNP) | VAF 40/93 reads (43%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as COSV52608282; called by muse, mutect2, varscan2
- TMEM8B | c.1256G>T p.G419V | Missense Mutation (SNP) | VAF 61/169 reads (36%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as COSV65078061; called by muse, mutect2, varscan2
- TRAPPC9 | c.1214C>T p.A405V | Missense Mutation (SNP) | VAF 20/61 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); catalogued as rs760322913, COSV66909985; called by muse, mutect2, varscan2
- UBQLN3 | c.1840G>C p.A614P | Missense Mutation (SNP) | VAF 27/65 reads (42%) | SIFT tolerated (0.13); PolyPhen benign (0.276); catalogued as COSV61164544, COSV61165906; called by muse, mutect2, varscan2
- UHRF1BP1 | c.3248C>T p.A1083V | Missense Mutation (SNP) | VAF 18/59 reads (31%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as COSV51960742; called by muse, mutect2
- UNC45B | c.1234C>G p.L412V | Missense Mutation (SNP) | VAF 49/110 reads (45%) | SIFT tolerated (1); PolyPhen benign (0.012); catalogued as COSV52100779; called by muse, mutect2, varscan2
- VCL | c.2767G>A p.V923M | Missense Mutation (SNP) | VAF 24/93 reads (26%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.157); catalogued as COSV53014821; called by muse, mutect2, varscan2
- ZDHHC21 | c.541A>G p.R181G | Missense Mutation (SNP) | VAF 6/51 reads (12%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.887); catalogued as COSV66615438; called by muse, varscan2
- ZNF479 | c.558A>T p.K186N | Missense Mutation (SNP) | VAF 81/302 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.592); catalogued as COSV58643816; called by muse, mutect2, varscan2
- ZNF638 | c.1963G>T p.V655L | Missense Mutation (SNP) | VAF 43/108 reads (40%) | SIFT tolerated (0.23); PolyPhen benign (0.017); catalogued as COSV52497291; called by muse, mutect2, varscan2
- ZNF835 | c.1070C>A p.T357N | Missense Mutation (SNP) | VAF 39/67 reads (58%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.46); catalogued as COSV73379765; called by muse, mutect2, varscan2
- MDC1 | c.1673del p.G558Dfs*10 | Frame Shift Del (DEL) | VAF 39/200 reads (20%) | called by mutect2, pindel, varscan2
- SUPT16H | c.1855_1876del p.Q619Kfs*21 | Frame Shift Del (DEL) | VAF 31/107 reads (29%) | called by mutect2, pindel, varscan2
- C2orf88 | c.282G>A p.G94= | Silent (SNP) | VAF 21/121 reads (17%) | catalogued as COSV61410897; called by muse, mutect2, varscan2
- CNTN1 | c.480C>G p.P160= | Silent (SNP) | VAF 24/105 reads (23%) | catalogued as rs771697105, COSV61645873; called by muse, mutect2, varscan2
- DGKH | c.1974C>T p.S658= | Silent (SNP) | VAF 25/54 reads (46%) | catalogued as COSV54942126; called by muse, mutect2, varscan2
- DLGAP3 | c.2067C>T p.G689= | Silent (SNP) | VAF 21/52 reads (40%) | catalogued as COSV52397850; called by muse, mutect2, varscan2
- GRIN2D | c.981G>A p.V327= | Silent (SNP) | VAF 4/12 reads (33%) | catalogued as COSV54382382; called by muse, mutect2
- KIAA1217 | c.5532A>T p.T1844= | Silent (SNP) | VAF 66/179 reads (37%) | catalogued as COSV56824135; called by muse, mutect2, varscan2
- LBP | c.6G>A p.G2= | Silent (SNP) | VAF 24/54 reads (44%) | catalogued as rs1439501010, COSV54143971; called by muse, mutect2, varscan2
- LTK | c.1440C>G p.A480= | Silent (SNP) | VAF 32/68 reads (47%) | catalogued as COSV53029361; called by muse, mutect2, varscan2
- MASP1 | c.1857C>T p.A619= | Silent (SNP) | VAF 55/124 reads (44%) | catalogued as COSV61831020; called by muse, mutect2, varscan2
- MRPS10 | c.18G>T p.A6= | Silent (SNP) | VAF 15/54 reads (28%) | catalogued as COSV50003103; called by muse, mutect2, varscan2
- MUC5B | c.2658C>T p.C886= | Silent (SNP) | VAF 45/90 reads (50%) | catalogued as rs769335872, COSV71595683; called by muse, mutect2, varscan2
- NCOA3 | c.3390A>G p.G1130= | Silent (SNP) | VAF 46/82 reads (56%) | catalogued as COSV59073647; called by muse, mutect2, varscan2
- NEB | c.3331C>T p.L1111= | Silent (SNP) | VAF 86/204 reads (42%) | catalogued as rs777827277, COSV51461135; called by muse, mutect2, varscan2
- PUS7L | c.423C>T p.A141= | Silent (SNP) | VAF 24/72 reads (33%) | catalogued as COSV61261224; called by muse, mutect2, varscan2
- TENM1 | c.3118C>T p.L1040= | Silent (SNP) | VAF 50/71 reads (70%) | catalogued as COSV64443833; called by muse, mutect2, varscan2
- UNC13C | c.5556T>A p.V1852= | Silent (SNP) | VAF 17/52 reads (33%) | catalogued as COSV52926363; called by muse, mutect2, varscan2
- C6orf223 | n.689G>T | RNA (SNP) | VAF 38/119 reads (32%) | catalogued as COSV60736084; called by muse, mutect2, varscan2
